Gene-level copy-number profile of specimen HCM-CSHL-0512-C24-85O from HCMI case HCM-CSHL-0512-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,746 days).
Specimen HCM-CSHL-0512-C24-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 60e1366c-b14d-4263-a950-857c4db94d83.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0512-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/f092b9d2-71fa-46b6-b6d2-b6d17d36d901

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,290; copy number 2: 45,952; copy number 3: 587; copy number 4: 175; copy number 5: 45; copy number 6: 101; copy number 7: 80; copy number 8: 26; copy number 9: 6; copy number 10: 50; copy number 11: 11; copy number 12: 3; copy number 13: 8; copy number 14: 6; copy number 15: 7; copy number 16: 9; copy number 17: 4; copy number 18: 1; copy number 19: 4; copy number 20: 5; copy number 21: 3; copy number 22: 1; copy number 23: 6; copy number 24: 20.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 396 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:69,123,512–71,302,864, 51 genes, copy number 6–7: VPS26A, RPS12P17, SUPV3L1, AL596223.1, HKDC1, AL596223.2, HK1, RPS15AP28, TACR2, ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B, LINC02651, RPL5P26, COL13A1, LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1, ADAMTS14, TBATA, RPS26P40, SGPL1, PCBD1, AC073176.2, AC073176.1, LINC02622, UNC5B, UNC5B-AS1.
- chr10:78,943,328–79,316,528, 3 genes, copy number 6: ZMIZ1-AS1, AL356753.1, ZMIZ1.
- chr12:48,559,882–48,957,487, 24 genes, copy number 5–6 (within-gene range 1–6): OR5BS1P, LALBA, OR11M1P, KANSL2, SNORA2C, MIR1291, SNORA2A, SNORA2B, CCNT1, TEX49, AC117498.1, ADCY6, MIR4701, ADCY6-DT, Y_RNA, CACNB3, DDX23, RND1, RNU6-600P, AC073610.1, AC073610.2, CCDC65, FKBP11, ARF3.
- chr12:51,328,442–51,812,864, 7 genes, copy number 6–7 (within-gene range 6–8): CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1.
- chr12:52,514,575–52,553,145, 2 genes, copy number 5: KRT5, KRT71.
- chr12:52,674,736–52,680,407, 1 gene, copy number 8: KRT1.
- chr12:52,746,596–52,753,821, 3 genes, copy number 5: AC055716.1, BTBD10P1, KRT127P.
- chr12:52,806,549–53,079,404, 13 genes, copy number 5–7: KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3.
- chr12:55,434,734–55,585,471, 2 genes, copy number 6 (within-gene range 3–6): AC122685.1, OR6C2.
- chr12:55,522,593–56,300,391, 62 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr12:57,738,013–57,896,482, 17 genes, copy number 6 (within-gene range 4–6): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1.
- chr12:57,983,795–58,395,138, 6 genes, copy number 5–6: AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:62,643,994–69,699,476, 163 genes, copy number 5–24 (broad region; genes not listed).
- chr12:70,638,073–72,670,758, 27 genes, copy number 7–11: PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr12:75,020,969–75,390,928, 8 genes, copy number 18–20: AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1.
- chr12:80,707,634–80,937,925, 7 genes, copy number 11–13 (within-gene range 1–13): MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.

Autosomal genes at a single copy (total copy number 1): 11,290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
